Surgical pathology report (de-identified scan), TCGA case TCGA-AF-A56L, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-A56L-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Adenocarcinoma, NOS
8140/3

Site: Colon, rectosigmoid
C19.9

9/12/17/12

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Rectosigmoid
- B. Appendix

CLINICAL NOTES

PRE-OP DIAGNOSIS: Rectosigmoid cancer.

GROSS DESCRIPTION

A. Received fresh, subsequently fixed in formalin labeled "rectosigmoid" is a 13 cm. long portion of colon. The specimen has a suture marking the distal portion. This end is inked black, the opposite end is inked blue. The ends of the specimen appear to be not stapled. The specimen is partially covered with pink-tan, smooth, glistening serosa and abundant yellow, lobular fat. There is no retroperitoneal reflection. The specimen is entirely covered with a portion of smooth, glistening serosa. The specimen is opened to show possibly circumferential tumor which is 4.5 x 4 x 1 cm. This comes to within 3.5 cm. of the distal margin. This shows gross evidence through muscularis propria and into the fat, coming to within 2.5 cm. of the radial margin. There is also a slight umbilication in the serosa (focus is inked blue). The remainder of the mucosa is pink-tan, smooth and glistening with normal to slightly dilated folds, both having an average circumference of 5 cm. Lymph nodes are grossly identified in the fat. Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY: #A1 - Representative luminal margin; A2 - tumor to serosal umbilication; A3 - tumor to fat; A4 - representative radial margin; A5, 6 - nine possible lymph nodes each; A7 - six possible lymph nodes; A8 - one possible lymph node; A9, 10 - one possibly necrotic or positive lymph node sectioned; A11 - 12 - largest possible lymph node, possibly centrally necrotic and positive. RS-12.

B. Received fresh, subsequently fixed in formalin labeled "appendix" is a grossly unremarkable appendix which is 9.5 x 0.7 cm. This is partially covered with pink-tan, smooth, glistening serosa and abundant yellow, lobular fat. The specimen is sectioned to show an intact wall with an average thickness of 0.3 cm. The lumen ranges from pinpoint to 0.3 cm. and is partially filled with red, dusky, diffluent material. No other discrete gross lesions are identified. Representative sections of the specimen are submitted in one cassette with the proximal end inked. RS-1.

MICROSCOPIC DESCRIPTION

- A. Histologic type: Invasive adenocarcinoma
Histologic grade: Moderately differentiated
Primary tumor (pT): Tumor invades through the muscularis propria into the pericolic fat to a depth of 5 mm. beyond the very attenuated muscularis propria (pT3b).
Proximal margin: Negative for tumor
Distal margin: Negative for tumor

[page 2 of 2]
Circumferential (radial) margin: Negative for tumor
Distance of tumor from closest margin: 2.5 cm. from radial margin and 3.5 cm. from distal margin
Vascular invasion: Lymphatic space invasion is identified in extranodal foci within the fat. No venous or arterial space invasion is identified.
Regional lymph nodes (pN): 10 of 23 lymph nodes are positive for metastatic carcinoma (pN2).
Non-lymph node pericolic tumor: Present
Distant metastasis (pM): Cannot evaluate, pMX
Other findings: The largest metastatic lymph node measures 1.4 cm. in greatest dimension. The surface of the carcinoma is extensively ulcerated. A mild, non-brisk, lymphocytic infiltrate is present associated with the tumor. Although the architectural features of the tumor are moderately differentiated, in many areas, the nuclear features of the tumor are more poorly differentiated.

B. Microscopic examination reveals an appendix with fibrous obliteration of the tip, no tumors are identified and no acute inflammation is identified.

5x1, 1x1

DIAGNOSIS

- A. Colon, rectosigmoid, segmental resection:
Invasive, moderately to poorly differentiated adenocarcinoma, invasive through muscularis propria into pericolic fat (pT3b).
The resection margins are negative for tumor.
Metastatic adenocarcinoma is present in 10 of 23 lymph nodes (pN2).
See microscopic description for template details.
- B. Appendix, excision:
Fibrous obliteration.

--- End Of Report ---

Source: NCI Genomic Data Commons file d6f2344b-b694-494e-b123-7a5173aa1aaa (TCGA-AF-A56L.CCA85476-406C-4512-89CE-3EAAA8782340.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).